Somatic mutation profile of tumor specimen C3L-03385-04 (aliquot CPT0239860006) from CPTAC case C3L-03385, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 72.3 years (26,404 days).
Specimen C3L-03385-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15a38798-ee8c-42dd-a267-37bec3b96df9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03385-32 (Blood Derived Normal), aliquot CPT0240540002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54961925-4436-415e-a627-8dd2b810dbc9

The open-access MAF lists 128 somatic variants for this specimen: 94 protein-altering or splice-affecting, 21 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 21, 5'UTR 5, Intron 4, Splice Region 4, Nonsense Mutation 4, RNA 3, In Frame Del 2, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs122445105, CM970157, COSV64872639; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 32/72 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ABCC12 | c.1897G>A p.V633M | Missense Mutation (SNP) | VAF 81/256 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs753704696, COSV60915738; called by muse, mutect2, varscan2
- ACVR1C | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1376322387, COSV54643947; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2017C>T p.R673W | Missense Mutation (SNP) | VAF 100/451 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1431912265; called by muse, mutect2, varscan2
- APLP1 | c.1342C>T p.Q448* | Nonsense Mutation (SNP) | VAF 90/229 reads (39%) | catalogued as COSV55702652; called by muse, mutect2, varscan2
- ATG9B | c.2336C>T p.P779L | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as rs756553369, COSV99871276; called by muse, mutect2, varscan2
- DNAH9 | c.4462G>A p.V1488I | Missense Mutation (SNP) | VAF 112/278 reads (40%) | SIFT tolerated (0.84); PolyPhen benign (0.022); catalogued as rs1247828636; called by muse, mutect2, varscan2
- DTX4 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs976950514; called by muse, mutect2, varscan2
- DVL1 | c.1649C>T p.P550L (on ENST00000378888 / NM_001330311.2; = p.P525L on NM_004421.3) | Missense Mutation (SNP) | VAF 56/90 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs375584920; called by muse, mutect2, varscan2
- DYSF | c.2848G>A p.V950M | Missense Mutation (SNP) | VAF 149/456 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.891); catalogued as rs568348073, COSV50270619; called by muse, mutect2, varscan2
- FAM135B | c.2101C>T p.R701* | Nonsense Mutation (SNP) | VAF 46/117 reads (39%) | catalogued as rs754073531, COSV52744808; called by muse, mutect2, varscan2
- GALNT9 | c.1009G>A p.G337R | Missense Mutation (SNP) | VAF 57/191 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs567959233; called by muse, mutect2, varscan2
- IFI16 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.021); catalogued as rs531846189; called by muse, varscan2
- IRAK4 | c.1276G>T p.V426F | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV101471795; called by muse, mutect2, varscan2
- ITGAM | c.1558C>T p.R520C (on ENST00000648685 / NM_001145808.2; = p.R519C on NM_000632.4) | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs200316294; called by muse, mutect2, varscan2
- LRP1B | c.6588A>G p.I2196M | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as COSV67246658; called by muse, mutect2, varscan2
- MAP2 | c.2579C>T p.T860M | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as rs772124563, COSV52288249; called by muse, mutect2, varscan2
- MED13 | c.2503C>T p.P835S | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67261949, COSV67262540, COSV67267788; called by muse, mutect2, varscan2
- MSANTD2 | c.898A>G p.S300G (on ENST00000374979 / NM_001308027.2; = p.S248G on NM_024631.4) | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.169); catalogued as rs1378280289; called by muse, mutect2, varscan2
- MSN | c.1523G>A p.R508H | Missense Mutation (SNP) | VAF 72/249 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1465848452, COSV64303704; called by muse, mutect2, varscan2
- MXRA5 | c.8144C>T p.T2715M | Missense Mutation (SNP) | VAF 120/379 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs756129853, COSV54238293; called by muse, mutect2, varscan2
- NBEAL1 | c.8059G>C p.E2687Q | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.524); catalogued as COSV68916968, COSV68917239; called by muse, mutect2, varscan2
- NTNG1 | c.1375C>T p.H459Y | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV64266759; called by muse, mutect2, varscan2
- OCA2 | c.1714C>T p.R572C | Missense Mutation (SNP) | VAF 364/820 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs374415755, COSV62342124; called by muse, mutect2, varscan2
- OSMR | c.691C>T p.L231F | Missense Mutation (SNP) | VAF 77/196 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.311); catalogued as COSV57091621, COSV99953019, COSV99953075; called by muse, mutect2, varscan2
- PCLO | c.11333C>A p.A3778E | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV61646402; called by muse, mutect2, varscan2
- PI4KB | c.2221C>T p.R741W (on ENST00000368873 / NM_001369623.1; = p.R753W on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 100/228 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55021170; called by muse, mutect2, varscan2
- PIK3CG | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 57/204 reads (28%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.183); catalogued as COSV63247367; called by muse, mutect2, varscan2
- PKHD1 | c.3839G>A p.R1280H | Missense Mutation (SNP) | VAF 96/289 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374233100; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PSPN | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.704); catalogued as rs568955242; called by muse, mutect2, varscan2
- PWWP3B | c.2063G>A p.R688Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs1569368779, COSV100531673; called by muse, mutect2, varscan2
- SLC4A3 | c.2750G>A p.R917H | Missense Mutation (SNP) | VAF 53/168 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.36); catalogued as rs1559204655; called by muse, mutect2, varscan2
- SNTG2 | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 75/247 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.41); catalogued as rs754085301, COSV57989621; called by muse, mutect2, varscan2
- SYT5 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 101/265 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV62831233; called by muse, mutect2, varscan2
- TRPV5 | c.235G>T p.G79W | Missense Mutation (SNP) | VAF 55/232 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54687260; called by muse, mutect2, varscan2
- TSHZ1 | c.1423C>T p.H475Y (on ENST00000580243 / NM_001308210.2; = p.H430Y on NM_005786.6) | Missense Mutation (SNP) | VAF 97/188 reads (52%) | SIFT tolerated (0.62); PolyPhen benign (0.098); catalogued as COSV59016708; called by muse, mutect2, varscan2
- TTK | c.2462C>G p.S821C | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100036358; called by muse, mutect2, varscan2
- UBC | c.1544A>G p.Y515C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV60059124; called by mutect2, varscan2
- USP26 | c.2092C>T p.R698* | Nonsense Mutation (SNP) | VAF 62/148 reads (42%) | catalogued as rs887422621, COSV63708329; called by muse, mutect2, varscan2
- VCPIP1 | c.2333G>A p.R778Q | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60050555; called by muse, mutect2, varscan2
- WNT2 | c.264C>A p.N88K | Missense Mutation (SNP) | VAF 165/425 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as rs921878179; called by muse, mutect2, varscan2
- ZNF215 | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 101/253 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs751369345; called by muse, mutect2, varscan2
- ZNFX1 | c.1339C>T p.R447* | Nonsense Mutation (SNP) | VAF 51/111 reads (46%) | catalogued as COSV65573550; called by muse, mutect2, varscan2
- ABCA8 | c.3309+3A>G | Splice Region (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2
- ABCB1 | c.2701A>C p.I901L | Missense Mutation (SNP) | VAF 77/451 reads (17%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- ABCG1 | c.372G>T p.K124N | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAM28 | c.1161del p.F387Lfs*63 | Frame Shift Del (DEL) | VAF 9/55 reads (16%) | called by mutect2, pindel
- ADGRV1 | c.6764A>T p.N2255I | Missense Mutation (SNP) | VAF 93/261 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ARHGAP44 | c.992T>A p.L331H | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ARRDC4 | c.820A>G p.I274V | Missense Mutation (SNP) | VAF 121/275 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ASPM | c.7330A>G p.T2444A | Missense Mutation (SNP) | VAF 172/361 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- AVIL | c.299A>T p.E100V | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BHLHE22 | c.344G>C p.S115T | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRINP1 | c.1930T>C p.S644P | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- CCNDBP1 | c.966A>G p.T322= | Splice Region (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- CCR3 | c.305G>T p.G102V | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- COL12A1 | c.3589G>A p.E1197K | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DARS1 | c.408G>C p.E136D | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- DDHD2 | c.890G>C p.R297T | Missense Mutation (SNP) | VAF 84/224 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- DNAH10 | c.3450+6C>A | Splice Region (SNP) | VAF 25/71 reads (35%) | called by muse, mutect2, varscan2
- DNMT3B | c.781G>T p.V261F | Missense Mutation (SNP) | VAF 88/245 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM155B | c.784G>C p.D262H | Missense Mutation (SNP) | VAF 152/367 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FOXI3 | c.639A>T p.P213= | Splice Region (SNP) | VAF 12/312 reads (4%) | called by muse, mutect2
- GABBR1 | c.1502A>G p.N501S | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.349); called by muse, mutect2
- GDF2 | c.542C>A p.A181D | Missense Mutation (SNP) | VAF 110/161 reads (68%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPR162 | c.967_969del p.F323del (on ENST00000311268 / NM_019858.2; = p.F39del on NM_014449.2) | In Frame Del (DEL) | VAF 112/291 reads (38%) | called by mutect2, pindel, varscan2
- HEATR6 | c.1286C>G p.S429C | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- HTR2C | c.690G>A p.M230I | Missense Mutation (SNP) | VAF 61/176 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- IGSF10 | c.7064C>A p.T2355K | Missense Mutation (SNP) | VAF 61/220 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- KCNT1 | c.2542G>C p.D848H (on ENST00000488444; = p.D867H on NM_020822.3) | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KIF21A | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRT71 | c.553A>T p.I185F | Missense Mutation (SNP) | VAF 220/518 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- LRIG2 | c.827C>A p.T276K | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- LRP6 | c.4107G>C p.Q1369H | Missense Mutation (SNP) | VAF 23/344 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.169); called by muse, mutect2
- NDNF | c.1610C>G p.P537R | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- NOP58 | c.1577A>T p.E526V | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PGK1 | c.1055C>G p.T352S | Missense Mutation (SNP) | VAF 24/232 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.37); called by muse, mutect2
- PTEN | c.69_74del p.D24_L25del | In Frame Del (DEL) | VAF 114/203 reads (56%) | called by mutect2, pindel, varscan2
- PTPRC | c.2673G>C p.Q891H | Missense Mutation (SNP) | VAF 10/306 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RAB43 | c.581C>G p.P194R | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RIC1 | c.4017G>C p.K1339N | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- RNF182 | c.587C>G p.S196C | Missense Mutation (SNP) | VAF 61/139 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RYR3 | c.2014T>G p.F672V | Missense Mutation (SNP) | VAF 73/291 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- SFMBT1 | c.2444G>A p.R815K | Missense Mutation (SNP) | VAF 88/198 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SIGLEC10 | c.925G>C p.E309Q | Missense Mutation (SNP) | VAF 131/294 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SLC39A12 | c.1966G>A p.V656I (on ENST00000377369 / NM_001145195.2; = p.V619I on NM_152725.3) | Missense Mutation (SNP) | VAF 60/86 reads (70%) | SIFT tolerated (0.13); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- SLFN5 | c.263A>T p.K88M | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TENM3 | c.7017T>A p.H2339Q | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- THOC2 | c.3946G>A p.E1316K | Missense Mutation (SNP) | VAF 10/276 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.197); called by muse, mutect2
- TRANK1 | c.3956G>A p.C1319Y | Missense Mutation (SNP) | VAF 81/246 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- TRIM77 | c.175T>G p.S59A | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- XK | c.751T>C p.Y251H | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ZNF2 | c.418G>C p.V140L (on ENST00000611147 / NM_001291605.2; = p.V127L on NM_021088.4) | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- BMP5 | c.357T>A p.S119= | Silent (SNP) | VAF 67/206 reads (33%) | called by muse, mutect2, varscan2
- BTBD7 | c.2529C>T p.A843= | Silent (SNP) | VAF 125/164 reads (76%) | catalogued as rs770087269; called by muse, mutect2, varscan2
- CACNA1F | c.498C>T p.L166= | Silent (SNP) | VAF 111/299 reads (37%) | called by muse, mutect2, varscan2
- COL6A3 | c.1218T>C p.R406= | Silent (SNP) | VAF 64/384 reads (17%) | catalogued as rs766367190; called by muse, mutect2, varscan2
- DCAF12L2 | c.1335G>A p.V445= | Silent (SNP) | VAF 60/130 reads (46%) | called by muse, mutect2, varscan2
- DLG3 | c.51C>T p.T17= | Silent (SNP) | VAF 139/500 reads (28%) | called by muse, varscan2
- DNAH17 | c.13284A>G p.K4428= | Silent (SNP) | VAF 83/258 reads (32%) | called by muse, mutect2, varscan2
- FLT4 | c.1482G>A p.T494= | Silent (SNP) | VAF 263/604 reads (44%) | catalogued as rs200647932; called by muse, mutect2, varscan2
- FRAS1 | c.642G>A p.P214= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as rs532528605, COSV53600358; called by muse, mutect2, varscan2
- IL17F | c.201C>T p.R67= | Silent (SNP) | VAF 104/258 reads (40%) | catalogued as rs751070725; called by muse, mutect2, varscan2
- MYO18B | c.6996C>T p.D2332= | Silent (SNP) | VAF 49/131 reads (37%) | catalogued as rs373119005; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO1D | c.2835T>C p.L945= | Silent (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2
- NLRP11 | c.387C>T p.F129= | Silent (SNP) | VAF 13/168 reads (8%) | catalogued as rs145807373; called by muse, mutect2
- SLC30A5 | c.483C>T p.I161= | Silent (SNP) | VAF 54/142 reads (38%) | called by muse, mutect2, varscan2
- SLC35G3 | c.921T>A p.P307= | Silent (SNP) | VAF 151/459 reads (33%) | called by muse, mutect2, varscan2
- TCERG1 | c.2091C>G p.L697= | Silent (SNP) | VAF 27/78 reads (35%) | called by muse, mutect2, varscan2
- TMEM151A | c.906C>T p.V302= | Silent (SNP) | VAF 67/178 reads (38%) | called by muse, mutect2, varscan2
- TMEM229A | c.549G>C p.G183= | Silent (SNP) | VAF 92/668 reads (14%) | called by muse, varscan2
- TRAPPC2L | c.183C>G p.L61= | Silent (SNP) | VAF 41/95 reads (43%) | called by muse, mutect2, varscan2
- VPS13D | c.9258G>A p.S3086= | Silent (SNP) | VAF 178/414 reads (43%) | catalogued as rs372487013; called by muse, mutect2, varscan2
- ZXDA | c.357G>A p.A119= | Silent (SNP) | VAF 70/189 reads (37%) | catalogued as rs776013779; called by muse, mutect2, varscan2
- ARL8B | c.-37T>A | 5'UTR (SNP) | VAF 90/484 reads (19%) | called by muse, mutect2, varscan2
- DHX16 | c.1544+795T>A | Intron (SNP) | VAF 86/224 reads (38%) | called by muse, mutect2, varscan2
- GOLGA4 | c.-7C>G | 5'UTR (SNP) | VAF 82/288 reads (28%) | catalogued as rs1224667198; called by muse, mutect2, varscan2
- GRM6 | c.1501-16G>A | Intron (SNP) | VAF 62/163 reads (38%) | called by muse, mutect2, varscan2
- MAP3K15 | c.*53A>C | 3'UTR (SNP) | VAF 34/125 reads (27%) | called by muse, mutect2, varscan2
- MIR374A | n.39G>A | RNA (SNP) | VAF 42/115 reads (37%) | called by muse, mutect2, varscan2
- NOS1 | c.2532-2197G>A | Intron (SNP) | VAF 41/95 reads (43%) | catalogued as rs564218603, COSV57617541; called by muse, mutect2, varscan2
- OR4F13P | n.855G>C | RNA (SNP) | VAF 65/168 reads (39%) | called by muse, mutect2, varscan2
- POU2F1 | c.-8-3200T>A | Intron (SNP) | VAF 13/146 reads (9%) | called by muse, mutect2
- RRP1 | c.-29C>T | 5'UTR (SNP) | VAF 220/558 reads (39%) | catalogued as rs374847231; called by muse, mutect2, varscan2
- SSX6P | n.74C>T | RNA (SNP) | VAF 27/251 reads (11%) | catalogued as rs150874433; called by muse, mutect2, varscan2
- SUMF2 | c.-12C>A | 5'UTR (SNP) | VAF 65/285 reads (23%) | catalogued as rs780302368; called by muse, mutect2, varscan2
- TPH2 | c.-46C>T | 5'UTR (SNP) | VAF 88/235 reads (37%) | called by muse, mutect2, varscan2
